Gene-level copy-number profile of tumor specimen TCGA-G4-6294-01A from TCGA case TCGA-G4-6294, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IV; Age at diagnosis: 76.0 years (27,755 days).
Specimen TCGA-G4-6294-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.c9bd0fa5-f732-49ad-96ea-fbdfda4ac95b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G4-6294-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2f5c1229-c96a-42d3-9c6c-81624f235fc0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 3,425; copy number 2: 49,442; copy number 3: 3,373; copy number 4: 1,944; copy number 5: 121; copy number 7: 1,508.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G4-6294-01A-11D-1770-01): tumor purity 0.81, ploidy 2.23, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:6,056,975–6,748,969, 6 genes (within-gene range 0–1): AC009135.1, AC006112.1, AC007223.1, AC007012.2, AC007012.1, RNU7-99P.
- chr16:7,004,007–7,004,112, 1 gene: RNU6-328P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,629 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:6,590,021–9,769,513, 56 genes, copy number 5 (within-gene range 4–5): C7orf26, ZNF853, ZNF316, AC073343.2, AC073343.1, ZNF12, PMS2CL, SPDYE20P, RSPH10B2, CCZ1B, OR7E39P, UNC93B2, OR7E136P, OR7E59P, AC079804.2, ALG1L5P, AC079804.1, FAM86LP, AC079804.3, MIR3683, AC092104.1, Y_RNA, C1GALT1, AC005532.2, AC005532.1, AC079448.1, COL28A1, AC004982.1, AC004982.2, MIOS, AC004948.1, RPA3, UMAD1, AC007161.3, AC007161.2, AC007161.1, RNU6-534P, CCNB2P1, AC006042.3, GLCCI1-DT, GLCCI1, AC006042.2, ICA1, AC006042.1, AC007009.1, AC007128.1, AC007128.2, NXPH1, AC009500.1, AC004852.2, AC004852.1, AC004852.3, GAPDHP68, AC060834.2, PER3P1, AC060834.1.
- chr7:35,632,659–36,782,789, 32 genes, copy number 7: HERPUD2, AC018647.2, AC018647.1, SEPTIN7-DT, AC007551.1, SEPTIN7, AC007551.2, RNU6-1085P, AC087072.1, SEPTIN7P3, PPP1R14BP4, AC083864.5, AC083864.2, AC083864.4, AC083864.1, AC083864.3, MARK2P13, AC078841.1, EEPD1, AC007327.1, AC007327.2, AC006960.1, AC006960.3, KIAA0895, Y_RNA, ANLN, AC006960.2, AOAH, AOAH-IT1, AC007349.4, AC007349.1, AC007349.3.
- chr7:37,683,843–37,951,936, 1 gene, copy number 7 (within-gene range 4–7): EPDR1.
- chr7:37,821,210–47,582,558, 188 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr13:19,422,877–114,337,626, 1,348 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr20:15,892,355–16,573,448, 4 genes, copy number 5 (within-gene range 4–5): AL079338.1, AL161941.1, PPIAP17, KIF16B.

Autosomal genes at a single copy (total copy number 1): 3,425. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
